Somatic mutation profile of tumor specimen C3L-01138-01 (aliquot CPT0199700006) from CPTAC case C3L-01138, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 62.2 years (22,715 days).
Specimen C3L-01138-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3a12305-92b3-4aef-a7a6-434dd5b9a93c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01138-31 (Blood Derived Normal), aliquot CPT0200380002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16e5422a-c6fd-4afc-8da1-21feae282fee

The open-access MAF lists 206 somatic variants for this specimen: 148 protein-altering or splice-affecting, 44 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 44, Nonsense Mutation 10, Frame Shift Del 5, 3'UTR 4, Intron 4, Splice Site 3, 5'UTR 3, RNA 2, Frame Shift Ins 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRIP1 | c.2493-1G>C p.X831_splice | Splice Site (SNP) | VAF 20/228 reads (9%) | catalogued as rs786203451, CS1512647, COSV52010278, COSV52010642, COSV99369411; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 136/340 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.14056C>G p.H4686D | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV68946337; called by muse, mutect2
- ABCB7 | c.1090G>C p.E364Q (on ENST00000373394 / NM_001271696.3; = p.E365Q on NM_004299.6) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.349); catalogued as COSV53718839; called by muse, mutect2, varscan2
- ACTL9 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 36/199 reads (18%) | catalogued as COSV61007083; called by muse, mutect2, varscan2
- ADGRL1 | c.3809G>A p.R1270Q (on ENST00000340736 / NM_001008701.3; = p.R1265Q on NM_014921.5) | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.245); catalogued as rs367988893; called by muse, mutect2, varscan2
- ADRA2C | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1237221094; called by muse, mutect2, varscan2
- AKT2 | c.187A>C p.M63L | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV60908745; called by muse, mutect2
- ANKRD28 | c.2294A>C p.Y765S | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1047992781; called by muse, mutect2
- C3 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 64/498 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs759153670, COSV55573459; called by muse, mutect2, varscan2
- CASP2 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.358); catalogued as COSV60082215; called by muse, mutect2, varscan2
- CRABP1 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55115446; called by muse, mutect2, varscan2
- CSMD3 | c.7035A>C p.Q2345H (on ENST00000297405 / NM_001363185.1; = p.Q2241H on NM_052900.3) | Missense Mutation (SNP) | VAF 58/371 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99830838; called by muse, mutect2, varscan2
- CTAGE9 | c.2201G>C p.R734P | Missense Mutation (SNP) | VAF 61/568 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs199637587, COSV100020663; called by muse, mutect2, varscan2
- ESX1 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV101006520, COSV65425378; called by muse, mutect2
- FMN2 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs772498975, COSV60417202; called by muse, mutect2, varscan2
- GABRA5 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59478103, COSV59478139; called by muse, mutect2, varscan2
- GPR78 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs754248787; called by muse, mutect2, varscan2
- H2BC12 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as rs776586709; called by muse, mutect2, varscan2
- KALRN | c.5045G>A p.R1682Q | Missense Mutation (SNP) | VAF 149/493 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as rs752824553; called by muse, mutect2, varscan2
- KIFAP3 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV63032018; called by muse, mutect2, varscan2
- MAGEC1 | c.2747C>T p.A916V | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776851614, COSV53578740; called by muse, mutect2, varscan2
- MAP1B | c.7003G>A p.A2335T | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs370354996; called by muse, varscan2
- MPP7 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as rs1212832072; called by muse, mutect2
- MUC4 | c.5269C>T p.Q1757* | Nonsense Mutation (SNP) | VAF 77/1874 reads (4%) | catalogued as rs1453803075; called by muse, mutect2
- MYH10 | c.4423G>A p.E1475K | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1255634637; called by muse, mutect2, varscan2
- MYO5A | c.5420G>A p.R1807H | Missense Mutation (SNP) | VAF 52/433 reads (12%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.511); catalogued as rs767265712; called by muse, mutect2, varscan2
- MYOM2 | c.3095T>G p.V1032G | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50794602; called by muse, mutect2, varscan2
- NAP1L3 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 42/151 reads (28%) | catalogued as COSV100220647; called by muse, varscan2
- NEBL | c.2944G>A p.V982I | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.09); catalogued as rs867653069, COSV65805131; called by muse, mutect2, varscan2
- NSD3 | c.4309G>T p.E1437* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | catalogued as rs1043561773, COSV57667920; called by muse, mutect2, varscan2
- OPRL1 | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 132/496 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61090838; called by muse, mutect2, varscan2
- OR52A1 | c.935C>G p.S312* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV61093428; called by muse, mutect2, varscan2
- PCDH17 | c.2323G>T p.E775* | Nonsense Mutation (SNP) | VAF 106/405 reads (26%) | catalogued as COSV64974415; called by muse, mutect2, varscan2
- PCDHA13 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.048); catalogued as rs782467193, COSV56496419, COSV56539642; called by muse, mutect2, varscan2
- PDZD8 | c.2293A>G p.I765V | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57825422; called by muse, mutect2, varscan2
- POGK | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 81/359 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.231); catalogued as COSV63311876; called by muse, mutect2, varscan2
- PROX1 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV54781545; called by muse, mutect2, varscan2
- PTCHD4 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs781124273; called by muse, mutect2, varscan2
- RPL10A | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV57690152; called by muse, mutect2, varscan2
- RXFP2 | c.2210T>G p.L737R | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs1349061875; called by muse, mutect2, varscan2
- SCAF8 | c.3775A>G p.S1259G | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as rs1482310902; called by muse, mutect2, varscan2
- SCN7A | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV69270672; called by muse, mutect2, varscan2
- SCN9A | c.4282G>T p.E1428* (on ENST00000303354; = p.E1417* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100312041; called by muse, mutect2, varscan2
- SOX9 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 57/388 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55425121; called by muse, mutect2, varscan2
- TCOF1 | c.3970G>A p.E1324K (on ENST00000377797 / NM_001135243.1; = p.E1247K on NM_000356.4) | Missense Mutation (SNP) | VAF 115/465 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1157784154; called by muse, mutect2, varscan2
- WDR45B | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 53/473 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs772141094, COSV66408594; called by muse, mutect2, varscan2
- WDR76 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV51040518; called by muse, mutect2, varscan2
- ZFYVE27 | c.900G>T p.E300D | Missense Mutation (SNP) | VAF 160/559 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61747284; called by muse, mutect2, varscan2
- ZNF28 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs377626728; called by muse, mutect2, varscan2
- ZNF420 | c.1395T>A p.H465Q | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100421154; called by muse, mutect2, varscan2
- ZNF528 | c.1097C>A p.S366Y | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV64621048; called by muse, mutect2, varscan2
- ZNF609 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1231740706; called by muse, mutect2, varscan2
- ZNF638 | c.3919A>G p.M1307V | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1441823472; called by muse, mutect2, varscan2
- ZSWIM2 | c.1259A>T p.K420I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54577019; called by muse, mutect2, varscan2
- ZSWIM4 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs755713293, COSV54320014; called by muse, mutect2, varscan2
- ABHD17A | c.347T>C p.F116S (on ENST00000292577 / NM_001130111.2; = p.F167S on NM_031213.4) | Missense Mutation (SNP) | VAF 108/326 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AC002094.3 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS3 | c.2381G>A p.S794N | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AGBL4 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- AGL | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALMS1 | c.6878C>T p.S2293L | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- APOB | c.3307G>C p.E1103Q | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BANF2 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 27/270 reads (10%) | called by muse, mutect2
- BRINP1 | c.634T>G p.S212A | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- BRSK1 | c.1485del p.S496Vfs*87 | Frame Shift Del (DEL) | VAF 31/102 reads (30%) | called by mutect2, pindel, varscan2
- CCDC174 | c.872T>G p.I291S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CD55 | c.828G>C p.W276C | Missense Mutation (SNP) | VAF 32/271 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP251 | c.1269+7A>G | Splice Region (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- CHUK | c.1679+1G>A p.X560_splice | Splice Site (SNP) | VAF 55/292 reads (19%) | called by muse, mutect2, varscan2
- CNDP1 | c.926C>T p.T309I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNOT8 | c.610A>C p.N204H | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CSMD2 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CSPG5 | c.994G>T p.V332F | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CTNNBL1 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 27/253 reads (11%) | called by muse, mutect2, varscan2
- DDA1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 60/201 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DDC | c.1187C>A p.P396H | Missense Mutation (SNP) | VAF 135/662 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- DGKH | c.1159G>T p.V387F | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMPK | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DOCK8 | c.1396C>G p.L466V | Missense Mutation (SNP) | VAF 144/342 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FAM227B | c.569A>T p.K190M | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- FGD6 | c.2198C>G p.S733C | Missense Mutation (SNP) | VAF 78/298 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FRMD3 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FST | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 83/177 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAS2L1 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GLB1L3 | c.1935C>G p.I645M | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- GLT6D1 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- GRIA1 | c.735G>C p.E245D | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GRIK4 | c.1889T>G p.L630R | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECTD4 | c.3636C>G p.I1212M | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IARS2 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); called by muse, mutect2
- IMPA1 | c.334G>C p.A112P | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by muse, mutect2
- INPP5D | c.616C>T p.L206F (on ENST00000445964 / NM_001017915.3; = p.L205F on NM_005541.5) | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF13B | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2
- KIR2DL3 | c.279C>G p.D93E | Missense Mutation (SNP) | VAF 186/526 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT15 | c.191dup p.M64Ifs*12 | Frame Shift Ins (INS) | VAF 46/143 reads (32%) | called by mutect2, pindel, varscan2
- KRT74 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LILRA5 | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 50/381 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- LOXHD1 | c.6677G>A p.S2226N (on ENST00000642948; = p.S2164N on NM_144612.7) | Missense Mutation (SNP) | VAF 122/705 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- LRP6 | c.1539G>C p.K513N | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- LRRN3 | c.1781A>C p.D594A | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- LRRTM3 | c.573C>A p.N191K | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYN | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- MAGEL2 | c.2761G>C p.D921H | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MAP2 | c.2093G>A p.R698K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- MICALL2 | c.2155C>G p.L719V | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MRGPRD | c.741G>C p.L247F | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.259); called by muse, mutect2
- MRPL21 | c.299A>T p.H100L | Missense Mutation (SNP) | VAF 41/1228 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2
- MUC6 | c.3596C>T p.P1199L | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- MYEF2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 96/625 reads (15%) | SIFT tolerated, low confidence (0.47); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MYO7A | c.3342G>C p.L1114F | Missense Mutation (SNP) | VAF 42/283 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAPB | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAV2 | c.4985_4989del p.A1662Vfs*2 | Frame Shift Del (DEL) | VAF 24/213 reads (11%) | called by mutect2, pindel, varscan2
- NBPF15 | c.992A>G p.H331R | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NOTCH1 | c.3301T>G p.C1101G | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OGFR | c.1964C>A p.A655D | Missense Mutation (SNP) | VAF 67/503 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- OR2L5 | c.662T>A p.L221H | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- P2RY14 | c.397C>G p.Q133E | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- PCDH15 | c.3758C>T p.S1253F | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- PNRC1 | c.252_253del p.V85Gfs*122 | Frame Shift Del (DEL) | VAF 117/778 reads (15%) | called by mutect2, pindel, varscan2
- POTEC | c.1197+1G>C p.X399_splice | Splice Site (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- PPP1R18 | c.1046T>C p.I349T | Missense Mutation (SNP) | VAF 54/357 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R26 | c.894G>T p.M298I | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRDM13 | c.1899G>T p.E633D | Missense Mutation (SNP) | VAF 85/490 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- PSAPL1 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2
- PWP1 | c.1088A>G p.D363G | Missense Mutation (SNP) | VAF 82/153 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- RELN | c.6261G>T p.W2087C | Missense Mutation (SNP) | VAF 761/1252 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RELT | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- RFX5 | c.1136C>A p.P379H | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SH2B2 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 41/458 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); called by muse, mutect2
- SLC16A2 | c.107_108dup p.P37Sfs*48 | Frame Shift Ins (INS) | VAF 53/280 reads (19%) | called by mutect2, pindel, varscan2
- SLC25A10 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 67/488 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SLC39A2 | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLC9A3 | c.684C>G p.Y228* | Nonsense Mutation (SNP) | VAF 114/484 reads (24%) | called by muse, mutect2, varscan2
- SMIM14 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SOX11 | c.1172_1184del p.S391Wfs*27 | Frame Shift Del (DEL) | VAF 49/447 reads (11%) | called by mutect2, pindel
- SOX8 | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TEP1 | c.5369G>T p.R1790L | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TIGD1 | c.942A>G p.I314M | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRA2A | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.246); called by muse, mutect2
- TSHZ3 | c.1415A>G p.K472R | Missense Mutation (SNP) | VAF 48/371 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- UPF3B | c.1149G>C p.E383D (on ENST00000276201 / NM_080632.3; = p.E370D on NM_023010.3) | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZFHX4 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.291); called by muse, mutect2
- ZFP69 | c.1566C>G p.F522L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- ZNF398 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF408 | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ZNF714 | c.1124del p.G375Afs*15 | Frame Shift Del (DEL) | VAF 100/376 reads (27%) | called by mutect2, pindel, varscan2
- ZNF85 | c.1141C>T p.H381Y | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2
- A1CF | c.1728T>C p.Y576= (on ENST00000373993 / NM_138932.2; = p.Y568= on NM_014576.4) | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- ADGRB3 | c.228G>A p.K76= | Silent (SNP) | VAF 20/210 reads (10%) | catalogued as rs1399073361; called by muse, mutect2
- ALMS1 | c.6141C>G p.S2047= | Silent (SNP) | VAF 29/161 reads (18%) | catalogued as rs960120562; called by muse, mutect2, varscan2
- ANO5 | c.324C>T p.L108= | Silent (SNP) | VAF 19/159 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.1185C>T p.I395= (on ENST00000359920 / NM_001130955.2; = p.I291= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs1396405837, COSV60466933; called by muse, mutect2, varscan2
- BHLHE23 | c.309C>G p.L103= (on ENST00000370346; = p.L119= on NM_080606.4) | Silent (SNP) | VAF 49/461 reads (11%) | catalogued as rs768672463; called by muse, mutect2, varscan2
- C11orf80 | c.1866G>T p.L622= | Silent (SNP) | VAF 34/286 reads (12%) | called by muse, mutect2, varscan2
- C2CD4B | c.687C>T p.S229= | Silent (SNP) | VAF 23/175 reads (13%) | catalogued as rs1273691719; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.397C>T p.L133= | Silent (SNP) | VAF 216/433 reads (50%) | called by muse, mutect2, varscan2
- ELOA2 | c.2127G>A p.R709= | Silent (SNP) | VAF 90/596 reads (15%) | called by muse, mutect2, varscan2
- FBN2 | c.507A>T p.G169= | Silent (SNP) | VAF 34/336 reads (10%) | catalogued as rs753414895; called by muse, mutect2
- H1-2 | c.579G>A p.V193= | Silent (SNP) | VAF 46/278 reads (17%) | catalogued as rs749431896; called by muse, mutect2, varscan2
- JAG1 | c.915G>T p.P305= | Silent (SNP) | VAF 58/408 reads (14%) | called by muse, mutect2, varscan2
- LGR5 | c.*2_*5del | Silent (DEL) | VAF 4/42 reads (10%) | called by pindel, varscan2
- LRRTM3 | c.574C>A p.R192= | Silent (SNP) | VAF 25/225 reads (11%) | catalogued as rs867047729; called by muse, mutect2, varscan2
- MCRS1 | c.528C>T p.Y176= | Silent (SNP) | VAF 37/248 reads (15%) | catalogued as rs1406114930; called by muse, mutect2, varscan2
- MDH1 | c.642A>G p.K214= | Silent (SNP) | VAF 34/111 reads (31%) | called by muse, mutect2, varscan2
- MED4 | c.429C>T p.I143= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs369517918; called by muse, mutect2, varscan2
- MKI67 | c.2433C>T p.F811= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as rs761987220; called by muse, mutect2
- MPLKIP | c.99G>A p.G33= | Silent (SNP) | VAF 60/552 reads (11%) | called by muse, mutect2, varscan2
- MSANTD3 | c.732C>G p.L244= | Silent (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- NADSYN1 | c.1290G>A p.R430= | Silent (SNP) | VAF 52/870 reads (6%) | called by muse, mutect2
- NOTCH3 | c.4779G>A p.Q1593= | Silent (SNP) | VAF 30/270 reads (11%) | called by muse, mutect2, varscan2
- OR2T27 | c.204C>T p.L68= | Silent (SNP) | VAF 24/345 reads (7%) | catalogued as rs1482103597; called by muse, mutect2
- PARP14 | c.894C>T p.F298= | Silent (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- PCDHA1 | c.2005C>T p.L669= | Silent (SNP) | VAF 67/475 reads (14%) | called by muse, mutect2, varscan2
- PRPF6 | c.264C>G p.L88= | Silent (SNP) | VAF 107/485 reads (22%) | called by muse, mutect2, varscan2
- RRN3 | c.1326G>A p.S442= | Silent (SNP) | VAF 22/282 reads (8%) | catalogued as rs559758942, COSV52213553; called by muse, mutect2, varscan2
- SGIP1 | c.84A>T p.P28= | Silent (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- SLC2A1 | c.1050C>G p.L350= | Silent (SNP) | VAF 102/1368 reads (7%) | called by muse, mutect2
- SLC49A3 | c.45G>A p.R15= | Silent (SNP) | VAF 31/161 reads (19%) | called by muse, mutect2, varscan2
- SMPD1 | c.309C>G p.L103= | Silent (SNP) | VAF 77/377 reads (20%) | called by muse, mutect2, varscan2
- SPTBN2 | c.5973G>C p.L1991= | Silent (SNP) | VAF 41/292 reads (14%) | called by muse, mutect2, varscan2
- STRADA | c.288C>T p.Y96= (on ENST00000336174 / NM_001363786.1; = p.Y59= on NM_153335.6) | Silent (SNP) | VAF 20/207 reads (10%) | catalogued as rs546795656, COSV55564688; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAF2 | c.960T>C p.A320= | Silent (SNP) | VAF 27/224 reads (12%) | catalogued as rs1252708421; called by muse, mutect2, varscan2
- TFAP2D | c.441C>G p.L147= | Silent (SNP) | VAF 45/268 reads (17%) | called by muse, mutect2, varscan2
- TMF1 | c.567G>A p.V189= | Silent (SNP) | VAF 19/198 reads (10%) | called by muse, mutect2, varscan2
- TRPM6 | c.4293T>G p.P1431= | Silent (SNP) | VAF 97/688 reads (14%) | called by muse, mutect2, varscan2
- TRRAP | c.6657G>A p.L2219= (on ENST00000359863 / NM_001244580.1; = p.L2201= on NM_003496.3) | Silent (SNP) | VAF 32/461 reads (7%) | called by muse, mutect2
- UMOD | c.181C>T p.L61= | Silent (SNP) | VAF 75/560 reads (13%) | catalogued as COSV56778966; called by muse, mutect2, varscan2
- UNC80 | c.2853C>T p.L951= | Silent (SNP) | VAF 30/213 reads (14%) | catalogued as COSV55882960; called by muse, mutect2, varscan2
- WDR74 | c.144G>C p.L48= | Silent (SNP) | VAF 65/406 reads (16%) | catalogued as rs1565223528; called by muse, mutect2, varscan2
- ZNF91 | c.1773A>G p.T591= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- ZYX | c.1230C>T p.F410= | Silent (SNP) | VAF 53/300 reads (18%) | catalogued as COSV51968552; called by muse, mutect2, varscan2
- AC100872.1 | chr8:122670527 A>G | 5'Flank (SNP) | VAF 17/122 reads (14%) | catalogued as rs529126252; called by muse, mutect2, varscan2
- AP004607.5 | n.164C>G | RNA (SNP) | VAF 18/127 reads (14%) | called by muse, mutect2, varscan2
- C19orf12 | c.-5G>A | 5'UTR (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- CYTL1 | c.*17G>C | 3'UTR (SNP) | VAF 42/315 reads (13%) | called by muse, mutect2, varscan2
- KLHL14 | c.-44+609C>T | Intron (SNP) | VAF 13/97 reads (13%) | catalogued as rs1471369518; called by muse, mutect2, varscan2
- MTERF4 | c.*1144C>T | 3'UTR (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- PMS2CL | n.930A>G | RNA (SNP) | VAF 207/631 reads (33%) | called by muse, mutect2, varscan2
- POMT1 | c.*48G>A | 3'UTR (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2
- PXMP2 | c.519+1173C>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- RFX4 | c.191+6492C>G | Intron (SNP) | VAF 30/182 reads (16%) | called by muse, mutect2, varscan2
- SIRT3 | c.*13C>A | 3'UTR (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- VPS35L | c.434-723G>A | Intron (SNP) | VAF 34/178 reads (19%) | catalogued as rs149674656; called by muse, mutect2, varscan2
- ZNF700 | c.-10C>T | 5'UTR (SNP) | VAF 46/526 reads (9%) | called by muse, mutect2
- ZXDA | c.-3G>A | 5'UTR (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
